Somatic mutation profile of tumor specimen 0DWWMU from CCDI case PBCPNG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 0.7 years (243 days).
Specimen 0DWWMU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4609799-6fb6-4bfc-8eab-b4831a8638a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWWME (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5375bbc3-0dfb-48f3-a733-35bcc6660e8e

The open-access MAF lists 19 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 4, 3'UTR 3, Splice Region 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3522C>G p.F1174L | Missense Mutation (SNP) | VAF 79/388 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs863225281, COSV66555460, COSV66556325; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CEACAM5 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 54/250 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs782807202, COSV55752130; called by muse, mutect2, varscan2
- ADGRF5 | c.1762A>T p.I588F | Missense Mutation (SNP) | VAF 61/236 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- BIRC6 | c.4008C>G p.C1336W | Missense Mutation (SNP) | VAF 15/432 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDV3 | c.627-3T>A | Splice Region (SNP) | VAF 8/70 reads (11%) | called by muse, varscan2
- FAM83H | c.2273C>A p.A758D | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- NLRP2 | c.445T>C p.F149L | Missense Mutation (SNP) | VAF 56/264 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- OR2W3 | c.452G>T p.C151F | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- SMTN | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 58/284 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TBX22 | c.511T>G p.C171G | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.489); called by muse, mutect2
- TRIM68 | c.121T>C p.S41P | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- NUP188 | c.2322A>G p.G774= | Silent (SNP) | VAF 89/235 reads (38%) | called by muse, mutect2, varscan2
- AC010542.3 | c.149-12148C>A | Intron (SNP) | VAF 40/112 reads (36%) | called by muse, mutect2, varscan2
- ASB16 | c.*98T>G | 3'UTR (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2, varscan2
- CACNA1A | c.5644-75A>G | Intron (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- EPPK1 | c.*5G>T | 3'UTR (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- LAYN | c.86-15G>T | Intron (SNP) | VAF 53/187 reads (28%) | called by mutect2, varscan2
- SIMC1 | c.1677+98T>C | Intron (SNP) | VAF 4/33 reads (12%) | catalogued as COSV104418257; called by muse, varscan2
- SLC2A10 | c.*81C>A | 3'UTR (SNP) | VAF 4/29 reads (14%) | called by mutect2, varscan2
